Somatic mutation profile of tumor specimen TCGA-TT-A6YP-01A (aliquot TCGA-TT-A6YP-01A-21D-A35I-08) from TCGA case TCGA-TT-A6YP, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 19.8 years (7,240 days).
Specimen TCGA-TT-A6YP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2827f420-878b-4c5a-966b-5bb4d3df3c9a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-TT-A6YP-10A (Blood Derived Normal), aliquot TCGA-TT-A6YP-10A-01D-A35G-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3f15bca3-de5c-4901-95ff-a239de927644

The open-access MAF lists 6 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 4, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MYOM2 | c.307C>T p.R103C | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.924); catalogued as rs1035230559, COSV50704762, COSV50797420; called by muse, mutect2
- FBN3 | c.3694G>A p.D1232N | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PAXIP1 | c.902G>A p.G301D | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- ZNF493 | c.1543C>G p.H515D | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT tolerated (0.66); PolyPhen benign (0.017); called by muse, mutect2
- FBN3 | c.8316C>G p.T2772= | Silent (SNP) | VAF 10/59 reads (17%) | called by muse, mutect2, varscan2
- PLPPR4 | c.1728C>T p.I576= | Silent (SNP) | VAF 5/40 reads (13%) | called by muse, mutect2, varscan2
